Surgical pathology report (de-identified scan), TCGA case TCGA-BF-A3DN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Cureline, specimen TCGA-BF-A3DN-01A (Primary Tumor).

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: Melanoma Histological description: Melanoma

Date of Procurement: Anatomic Site: Skin Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: Frozen

Container: cryomold Type of Procurement: Surgery Grade: 2

T Stage: 4 N Stage: 3 M Stage: 0 Treatment: no

Treatment Details: no/no

1CD-0-3

Melanoma, NOS 8720/3
Site: SKIN, NOS C44.9

Normal Sample

Anatomic Site: Blood Sample Type: normal Type of Procurement: Blood draw

Matrix: Blood Specimen Format: Frozen Container: tube

Date of Procurement:

hw
10/15/11

Bilateral/Synchronous Primary Neoplasms		

Source: NCI Genomic Data Commons file 03d82924-debe-4d67-8771-a6388f1f0183 (TCGA-BF-A3DN.4CBF8716-B8CC-4A4C-8ACC-59F0AF1A7A79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).